Somatic mutation profile of tumor specimen TCGA-XP-A8T6-01A (aliquot TCGA-XP-A8T6-01A-11D-A36J-09) from TCGA case TCGA-XP-A8T6, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 54.4 years (19,886 days).
Specimen TCGA-XP-A8T6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91ad6510-e3c0-45af-9664-20cc405ddbc1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XP-A8T6-10A (Blood Derived Normal), aliquot TCGA-XP-A8T6-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a66a5fe7-12c0-489d-8a9e-f6b74c2cf8ee

The open-access MAF lists 99 somatic variants for this specimen: 72 protein-altering or splice-affecting, 22 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 22, Nonsense Mutation 3, Frame Shift Del 2, Intron 2, Nonstop Mutation 1, Splice Site 1, 5'UTR 1, Frame Shift Ins 1, Splice Region 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAG1 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs104894289, CM981692, COSV100200812; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 29/73 reads (40%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CPS1 | c.8G>A p.R3K | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as rs750705469; called by muse, mutect2, varscan2
- CPT1B | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as rs1423499725, COSV56416375; called by muse, mutect2, varscan2
- DST | c.20647A>G p.I6883V (on ENST00000361203 / NM_001374722.1; = p.I4580V on NM_015548.5) | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.9); PolyPhen benign (0.084); catalogued as rs752769638, COSV99759749; called by muse, mutect2, varscan2
- ECPAS | c.5394G>T p.W1798C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV99397894; called by muse, mutect2
- FHIT | c.250-2A>G p.X84_splice | Splice Site (SNP) | VAF 15/51 reads (29%) | catalogued as rs1386677788; called by muse, mutect2, varscan2
- ITGA3 | c.2794C>T p.R932* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as rs776593477; called by muse, mutect2, varscan2
- KAT6A | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV55907981; called by muse, mutect2, varscan2
- KIAA0753 | c.1952G>A p.R651K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.257); catalogued as rs1258689371; called by muse, mutect2, varscan2
- MS4A14 | c.1364T>C p.M455T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs780026614; called by muse, mutect2, varscan2
- MS4A6E | c.199G>A p.G67S | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1229952154; called by muse, mutect2, varscan2
- MYH15 | c.4100C>A p.A1367D | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as COSV56321409; called by muse, mutect2, varscan2
- NLRC3 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1164084822; called by muse, mutect2, varscan2
- NR5A2 | c.271G>A p.D91N (on ENST00000367362 / NM_205860.3; = p.D45N on NM_003822.5) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52648247; called by muse, mutect2, varscan2
- PACC1 | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs369443875; called by muse, mutect2, varscan2
- PADI4 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs767499070, COSV64922903; called by muse, mutect2, varscan2
- PCMTD1 | c.136T>C p.Y46H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV62124449; called by muse, mutect2, varscan2
- PIK3CG | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100783114, COSV63245916; called by muse, mutect2
- PLA1A | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.839); catalogued as rs141940849, COSV56333664; called by muse, mutect2, varscan2
- PQBP1 | c.459A>C p.R153S | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.62); PolyPhen benign (0.354); catalogued as rs782495605, CD033719; called by muse, mutect2, varscan2
- PSME3 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1205199177, COSV53200116; called by muse, mutect2, varscan2
- RENBP | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs782506926; called by muse, mutect2, varscan2
- SCN11A | c.3151C>A p.Q1051K | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as COSV56570252; called by muse, mutect2, varscan2
- SLITRK4 | c.1340G>T p.G447V | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100567072; called by muse, varscan2
- TANC2 | c.14G>A p.S5N | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV67333542; called by muse, mutect2, varscan2
- TBL3 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749067239, COSV100224919, COSV60340970; called by mutect2, varscan2
- TMC4 | c.1906A>G p.I636V (on ENST00000617472 / NM_001145303.3; = p.I630V on NM_144686.4) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.149); catalogued as rs748646342; called by muse, mutect2, varscan2
- TMEM26 | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as COSV99515766; called by muse, mutect2, varscan2
- UBQLNL | c.557C>A p.S186Y | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV66494298; called by muse, mutect2
- ZNF479 | c.896G>C p.C299S | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99044431; called by muse, mutect2
- ZZEF1 | c.3298G>T p.A1100S | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as rs745636921; called by muse, mutect2, varscan2
- ACOX1 | c.1576G>T p.A526S | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- AKAP9 | c.3837G>T p.K1279N | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- ARAP2 | c.126T>A p.N42K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- CDK16 | c.1467C>G p.F489L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- COG5 | c.1781A>G p.D594G (on ENST00000347053 / NM_001379512.1; = p.D615G on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- DKK4 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- DMTF1 | c.212dup p.S72Ifs*11 | Frame Shift Ins (INS) | VAF 27/126 reads (21%) | called by mutect2, pindel, varscan2
- DNAH7 | c.5878G>C p.A1960P | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- EXT1 | c.1952A>T p.N651I | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- FAM166B | c.273C>G p.I91M | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- FIGN | c.148T>C p.Y50H | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GOLGB1 | c.802T>G p.L268V | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GPRC5C | c.1289G>A p.G430E (on ENST00000652232; = p.G385E on NM_018653.4) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- GRIA1 | c.1994_2018del p.E665Afs*16 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | called by mutect2, pindel
- HNRNPR | c.934G>A p.G312R | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- HSD17B13 | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- IFNA10 | c.177C>A p.F59L | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- IL18RAP | c.1254C>A p.S418R | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.092); called by muse, mutect2
- JHY | c.578G>T p.S193I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LILRB1 | c.1736A>T p.E579V (on ENST00000427581; = p.E529V on NM_006669.6) | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- LRP1B | c.12634C>A p.L4212M | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- MACROD2 | c.1121A>G p.Q374R (on ENST00000642719; = p.Q346R on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); called by muse, varscan2
- MCM3AP | c.905G>T p.R302M | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- MRPL3 | c.944C>A p.P315Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- NEDD9 | c.1408G>A p.V470I | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR2J3 | c.811C>G p.Q271E | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.138); called by muse, mutect2
- PCDHB14 | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- PELI3 | c.654G>A p.E218= | Splice Region (SNP) | VAF 19/115 reads (17%) | called by muse, mutect2, varscan2
- PTPN4 | c.935G>C p.R312T | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.02); called by muse, mutect2
- R3HDM2 | c.2749A>G p.T917A | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- REV3L | c.4561G>T p.G1521C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- SAP130 | c.3146A>G p.*1049Wext*31 | Nonstop Mutation (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- SEMA3A | c.718G>C p.D240H | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TINAGL1 | c.1283del p.G428Afs*55 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | called by mutect2, pindel, varscan2
- TLR7 | c.1798A>T p.K600* | Nonsense Mutation (SNP) | VAF 22/53 reads (42%) | called by muse, mutect2, varscan2
- TNRC6B | c.5218A>G p.S1740G (on ENST00000454349 / NM_001162501.2; = p.S1630G on NM_015088.3) | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- UBE3C | c.1150G>A p.G384S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF135 | c.1025C>A p.T342N (on ENST00000313434 / NM_001289401.2; = p.T354N on NM_003436.4) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- ZNF804B | c.682C>A p.H228N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ZNF836 | c.1438A>T p.S480C | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- ADCY2 | c.2958C>T p.A986= | Silent (SNP) | VAF 10/149 reads (7%) | called by muse, mutect2
- ADCY8 | c.448C>A p.R150= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as rs1257003108, COSV99651556; called by muse, mutect2, varscan2
- BCLAF1 | c.1794C>T p.S598= | Silent (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- CACHD1 | c.3204G>A p.V1068= | Silent (SNP) | VAF 43/113 reads (38%) | catalogued as rs368444781; called by muse, mutect2, varscan2
- EEF2KMT | c.57C>T p.R19= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as rs1242973161; called by muse, mutect2, varscan2
- FABP1 | c.21C>T p.Y7= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs1325102601; called by muse, mutect2, varscan2
- FAT2 | c.4725G>T p.L1575= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- FBN2 | c.1338C>A p.G446= | Silent (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
- HM13 | c.310C>T p.L104= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV59435888; called by muse, mutect2, varscan2
- MARCHF4 | c.195C>T p.H65= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV56108966; called by muse, mutect2, varscan2
- OPN5 | c.1032T>C p.S344= | Silent (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
- OR5T2 | c.657T>C p.D219= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as rs1565082663; called by muse, mutect2, varscan2
- PCDHB13 | c.1797C>T p.N599= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs1312931213; called by muse, mutect2, varscan2
- PRAMEF10 | c.450C>T p.F150= | Silent (SNP) | VAF 60/297 reads (20%) | catalogued as rs774712078; called by muse, mutect2, varscan2
- RNF122 | c.342C>T p.A114= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs777531296; called by muse, mutect2, varscan2
- SKI | c.693G>T p.L231= | Silent (SNP) | VAF 33/67 reads (49%) | called by muse, mutect2, varscan2
- TRIM15 | c.486C>A p.I162= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV64989178; called by muse, mutect2
- UFL1 | c.984G>A p.L328= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs921366878; called by muse, mutect2, varscan2
- WDR91 | c.996C>A p.R332= | Silent (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- XPNPEP2 | c.570G>T p.L190= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV64367847; called by muse, mutect2, varscan2
- ZNF70 | c.996C>T p.G332= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs752943786, COSV59532005; called by muse, mutect2, varscan2
- ZNF772 | c.207A>T p.T69= | Silent (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- ANKRD13D | c.*1283C>T | 3'UTR (SNP) | VAF 9/56 reads (16%) | catalogued as rs1477660989, COSV57386857; called by muse, mutect2, varscan2
- DHRS4L1 | n.437+4116C>G | Intron (SNP) | VAF 12/80 reads (15%) | called by muse, varscan2
- KLHL6 | c.-2C>T | 5'UTR (SNP) | VAF 16/79 reads (20%) | catalogued as rs755964120; called by muse, mutect2, varscan2
- RPS2 | c.376-87_376-86del | Intron (DEL) | VAF 16/71 reads (23%) | called by pindel, varscan2
- SNORD115-29 | n.2G>T | RNA (SNP) | VAF 51/121 reads (42%) | called by muse, mutect2, varscan2
